Gene-level copy-number profile of tumor specimen TCGA-55-6969-01A from TCGA case TCGA-55-6969, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 52.8 years (19,270 days).
Specimen TCGA-55-6969-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.3bd2198f-33b1-40ea-aa9e-c25ff8f11b3a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-6969-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/38b17020-d804-448b-b7d0-8c2e2972b656

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 1,037; copy number 2: 28,769; copy number 3: 18,630; copy number 4: 8,330; copy number 5: 1,081; copy number 6: 481; copy number 7: 1,105; copy number 8: 343; copy number 10: 35.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-6969-01A-11D-1943-01): tumor purity 0.25, ploidy 2.59, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,039 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:160,753,428–162,601,792, 16 genes, copy number 5: AC069224.1, PPM1L, B3GALNT1, NMD3, AC108738.1, EEF1GP4, PSMC1P7, SPTSSB, LINC02067, AC112491.1, RPL23AP42, OTOL1, AC112770.1, AC131211.1, TOMM22P6, AC128716.1.
- chr5:58,198–45,895,970, 710 genes, copy number 6–8 (broad region; genes not listed).
- chr7:104,667,749–104,926,645, 5 genes, copy number 8 (within-gene range 4–8): EIF4BP6, LHFPL3-AS1, AC091286.1, LHFPL3-AS2, RN7SL8P.
- chr8:37,597,480–56,075,274, 316 genes, copy number 5–10 (broad region; genes not listed).
- chr8:71,675,300–145,066,685, 1,153 genes, copy number 5–7 (broad region; genes not listed).
- chr20:10,672,695–11,345,855, 9 genes, copy number 5: AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1, AL049649.1, RPS11P1.
- chr20:13,389,392–13,638,932, 1 gene, copy number 5 (within-gene range 3–5): TASP1.
- chr20:13,714,322–16,053,197, 21 genes, copy number 5 (within-gene range 1–5): ESF1, NDUFAF5, SEL1L2, RNU6-278P, MACROD2, RPS3P1, AIMP1P1, RN7SL864P, FLRT3, RNU6-228P, AL121582.1, RNF11P2, MACROD2-IT1, RPS10P2, MACROD2-AS1, AL138808.1, RNU6-1159P, RNU6-115P, RNA5SP475, AL121584.1, ENSAP1.
- chr20:17,209,060–17,609,919, 11 genes, copy number 6: RNU1-131P, AL359511.2, AL359511.3, PCSK2, DYNLT3P1, BFSP1, RPS27AP2, AL132765.2, DSTN, RN7SKP69, AL132765.1.
- chr20:18,567,453–18,766,644, 2 genes, copy number 5 (within-gene range 4–5): AL121900.1, DTD1.
- chr20:18,642,782–20,370,949, 26 genes, copy number 5: DUXAP7, DTD1-AS1, EEF1A1P34, LINC00652, LINC00653, SCP2D1-AS1, SCP2D1, AL135936.1, AL136090.2, SLC24A3, AL136090.1, SLC24A3-AS1, AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1, RN7SL690P, AL161658.1, INSM1.
- chr20:21,569,976–24,446,314, 71 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).
- chr20:24,491,472–24,502,345, 1 gene, copy number 7: AL157413.1.
- chr20:36,045,618–64,313,132, 697 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 951. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
